Surgical pathology report (de-identified scan), TCGA case TCGA-09-0365, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site UCSF, specimen TCGA-09-0365-01A (Primary Tumor).

[page 1 of 4]
Specimen(s) Received

A: Left Ovary
[redacted]
H&E, First x 1, H&E, First x 1, H&E, First x 1, H&E, First x 1, H&E, First x 1, H&E, First x 1, H&E, First x 1, H&E, First x 1
B: Cervix, uterus BSO
[redacted]
H&E, First x 1, H&E, First x 1, H&E, First x 1, H&E, First x 1, H&E, First x 1, H&E, First x 1
[redacted]
H&E, First x 1
D: Sigmoid Adhesion Biopsy
[redacted]
H&E, First x 1
E: Sigmoid Tumor
[redacted]
H&E, First x 1
F: Left Pelvic Lymph Node
[redacted]
H&E, First x 1
G: Omentum
[redacted]
H&E, First x 1, H&E, First x 1
H: Ileum Nodule
[redacted]
H&E, First x 1
I: Ligament of Treitz Nodule
[redacted]
H&E, First x 1
J: Appendix
[redacted]
H&E, First x 1, H&E, First x 1
K: Ovary [redacted] (372-1,2,3,4,5 & 7)
[redacted]
H&E, First x 1, H&E, First x 1, H&E, First x 1, H&E, First x 1, H&E, First x 1, H&E, First x 1

Final Pathologic Diagnosis:
A. Left ovary, oophorectomy: Poorly differentiated (grade III) serous carcinoma;
see comment.
B. Uterus, cervix, fallopian tubes, and right ovary, TAH/BSO:
-Cervix: No significant abnormality.
-Endometrium: Atrophic pattern.
-Myometrium: No significant abnormality.
-Serosa: Metastatic serous carcinoma.
-Left and right fallopian tubes: No significant abnormality.
-Right ovary: No significant abnormality.

[page 2 of 4]
-
- C. Left infundibular ligament, biopsy: Metastatic serous carcinoma.
- D. Sigmoid adhesion, biopsy: Fibrosis, no evidence of carcinoma.
- E. Sigmoid colon serosa, biopsy: Metastatic serous carcinoma.
- F. Left pelvic lymph nodes, biopsy: No tumor identified (0/2).
- G. Omentum, omentectomy: Metastatic serous carcinoma.
- H. Ileum, serosa, biopsy: Metastatic serous carcinoma; fibrosis; necrosis; calcifications.
- I. Ligament of Treitz, biopsy: Fibrosis and chronic inflammation; no tumor identified.
- J. Appendix, appendectomy: Microfoci of metastatic serous carcinoma, fibrosis, and calcifications on the serosa.

Note:
Type of tumor: Serous carcinoma.
Grade of tumor: III.
Site of tumor: Unilateral, left ovary.
Location of tumor: Surface and parenchyma of ovary.
Condition of capsule: Tumor grows through capsule.
Cut surface: Solid and cystic.
Necrosis: Extensive.
Lymphatic/vascular invasion: Absent
Sites of metastasis in pelvis: Uterine serosa, microfoci; left Infundibular ligament, 1.0 cm.
Pelvic lymph nodes: 0/2.
Sites of metastasis in abdomen: Omentum, 3.1 cm; appendix, microfoci; ileum, 0.5 cm; sigmoid colon, 1.8 cm.
Para-aortic lymph nodes: None sampled.
Peritoneal cytology: Not collected.
FIGO stage: IIIC.
TNM stage: pT3cN0MX.

Intraoperative Consult Diagnosis
FS1 **Site, procedure:** Adenocarcinoma, probably serous, high grade.

Clinical History
The patient is a with ovarian cancer, who undergoes a total abdominal hysterectomy, bilateral salpingo-oophorectomy with pelvic lymph node dissection, omentectomy and appendectomy.

Gross Description
The specimen is received in ten parts, each labeled with the patient's name and number.
Part A, received fresh and labeled "left ovary," consists of an 11.5 x 11.0 x 4.3 cm mass of pink-tan, lobulated, sponge-like, friable tissue. Section is submitted for frozen section as FS1; the remainder of the frozen tissue is submitted in cassette A1. The specimen is serially sectioned, revealing a sponge-like consistency throughout, except for a focal, firm area measuring 2.0 x 1.7 x 1.5 cm. No cyst capsule is

[page 3 of 4]
SURGICAL PATHOLOGY WORKING DRAFT UCSF OVLANK # 372

noted. There is no fallopian tube present. Cassettes are submitted are submitted as follow:

Cassette A2: Firm nodule.

Cassettes A3-A8: Representative samples of the tumor.

Part B, received fresh and labeled "cervix, uterus, BSO," consists of of a uterus with attached cervix, fallopian tubes, and right ovary, weighing 2.3 gm. The uterus measures 3.5 cm from cornu to cornu, 3.0 cm from anterior to posterior and 6.3 cm from fundus to cervix. It is oriented by the relationship of the round ligaments to the fallopian tube. The serosa is speckled, with white-tan, papillary lesions, the largest measuring 0.4 cm in greatest diameter. Most are smaller than this. There are also some noticed on the adnexa. The cervix measures 2.5 cm in length and 3.0 cm in greatest diameter. The uterus is opened along its lateral borders. The transformation zone and endocervical canal are unremarkable. The endometrium is tan, measures 3.0 mm in thickness and contains no polyps. The myometrium measures 0.7 cm and contains no leiomyomas. The right fallopian tube measures 4.5 cm in length and approximately

0.5 cm in average diameter. The fimbriae are blunted. On cut section, the tube is unremarkable. The right ovary has been bisected; it measures 2.0 x 1.4 cm. The surface is smooth and contains adhesions. On cut section, the ovary is unremarkable. The left fallopian tube measures 4.5 cm in length. The fimbriae are not identified, and on cut section, the tube appears unremarkable. There is an oval pouch filled with brown-red, firm tissue connected to the adnexa below the left ovary, measuring 2.1 x 1.2 x 0.3 cm.

Cassettes are submitted as follow:

Cassette B1: Anterior cervix.

Cassette B2: Posterior cervix.

Cassette B3: Anterior endomyometrium.

Cassette B4: Posterior endomyometrium.

Cassette B5: Right fallopian tube and right ovary.

Cassette B6: Left fallopian tube and left cyst.

Part C, received in formalin and labeled "left infundibular ligament," consists of a single fragment of rubbery, red-tan tissue measuring 1.5 x 0.9 x 0.3 cm. The specimen is submitted entirely in cassette C1. Part D, received in formalin and labeled "sigmoid adhesion biopsy," consists of a single, tan-brown tissue fragment measuring 0.6 x 0.4 x 0.3 cm. It is submitted entirely in cassette D1.

Part E, received in formalin and labeled "sigmoid tumor," consists of multiple fragments of red-tan tissue measuring 1.8 x 1.3 x 0.5 cm in aggregate. They are submitted entirely in cassette E1.

Part F, labeled "left pelvic lymph node," consists of a single, brown-tan ovoid tissue fragment measuring 0.8

x 0.4 x 0.3 cm. It is bisected and submitted entirely in cassette F1.

Part G, labeled "omentum," consists of a single piece of yellow-tan, fibroadipose tissue measuring 33.0 x 5.5

x 1.2 cm. Grossly, there is an area of tan-pink, friable papillary tissue, similar to the neoplastic tissue of the ovary. This nodule measures 3.1 x 2.2 x 1.0 cm. Its margins are indistinct. The specimen is serially sectioned and a representative section is submitted in cassette G1. A section of the tumor is submitted in cassette G2.

Part H, labeled "ileum nodule," consists of a fragment of yellow-tan, fibroadipose tissue measuring 1.0 x 0.5

x 0.1 cm, and a red-tan nodule measuring 0.5 x 0.2 x 0.2 cm. Both are submitted entirely in cassette H1.

Part I, labeled "ligament of Treitz nodule," consists of a single tissue fragment measuring 1.5 cm in length and 0.1 cm in diameter. It is submitted entirely in cassette I1.

Part J, labeled "appendix," consists of an appendix measuring 5.2 cm in length and 0.5 cm in average diameter. The serosa is smooth and glistening. The specimen is serially sectioned, with the proximal margin indicated by a cut. The appendix is unremarkable. Proximal sections are submitted in cassette J1 and distal sections are submitted in cassette J2.

[page 4 of 4]
[REDACTED]

[REDACTED]

[REDACTED]

The correct weight of the specimen received in part B is 67.0 grams. The weight of the uterus alone is 37.0 grams. The weight of the left ovary is 285.3 grams.

[REDACTED]

Specimen(s) Received: Vaginal, Thin Prep

Final Diagnosis

Vaginal, Thin Prep
CELLULAR CHANGES WITHIN NORMAL LIMITS.
Atrophic changes
SPECIMEN ADEQUACY:
Satisfactory for evaluation.

[REDACTED]

[REDACTED]

Signed: 04/18/2019 10:15

Specimen(s) Received: Cervical/Endocervical, Thin Prep

Final Diagnosis

Cervical/Endocervical, Thin Prep
CELLULAR CHANGES WITHIN NORMAL LIMITS.
Atrophic pattern
SPECIMEN ADEQUACY:
Satisfactory for evaluation. Endocervical cells present.

[REDACTED]

Source: NCI Genomic Data Commons file 75b050fe-84fc-4a69-9c27-23d9792f5045 (TCGA-09-0365.459F8DF7-B386-47C6-BF17-73AF831441D4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).